Somatic mutation profile of tumor specimen TCGA-EK-A2RO-01A (aliquot TCGA-EK-A2RO-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 59.8 years (21,844 days).
Specimen TCGA-EK-A2RO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cecfb47-4152-4113-a395-e01484a8ce4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RO-10A (Blood Derived Normal), aliquot TCGA-EK-A2RO-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd692ad4-86bb-4618-9e21-74af2c5f5f12

The open-access MAF lists 131 somatic variants for this specimen: 102 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 27, Nonsense Mutation 12, In Frame Del 1, Frame Shift Del 1, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL2L11 | c.467G>A p.G156E (on ENST00000393256 / NM_138621.5; = p.G96E on NM_006538.5) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58029627; called by muse, mutect2
- CXCR4 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as rs104893624, CM030831, COSV54010080; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 48/79 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.9484C>T p.R3162* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as rs376273529; called by muse, mutect2, varscan2
- ABTB2 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54387628; called by muse, mutect2, varscan2
- ACACB | c.2023C>T p.R675W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs202216589; called by muse, mutect2, varscan2
- ADGRB2 | c.4133C>T p.P1378L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.161); catalogued as rs770816146, COSV57071074; called by muse, mutect2, varscan2
- AJUBA | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs768530887, COSV52985232; called by muse, mutect2, varscan2
- AKAP6 | c.5505G>C p.E1835D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV55213612; called by muse, mutect2, varscan2
- ANK2 | c.10693G>A p.E3565K | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.574); catalogued as rs786205727, COSV52160624; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP6 | c.2551G>A p.E851K (on ENST00000337414 / NM_013427.3; = p.E648K on NM_013423.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.114); catalogued as rs1012531076, COSV57295804; called by muse, mutect2, varscan2
- ARMCX2 | c.1896C>G p.F632L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.899); catalogued as COSV57530014; called by muse, mutect2, varscan2
- ATP7A | c.3442G>T p.V1148F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV58446257; called by muse, mutect2, varscan2
- ATRNL1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV61803792, COSV61803975; called by muse, mutect2, varscan2
- ATXN7L2 | c.1081T>C p.C361R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV60204811; called by muse, mutect2, varscan2
- BEST3 | c.1858G>C p.D620H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV58301433; called by muse, mutect2, varscan2
- C4orf46 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs140932563, COSV57014918; called by muse, mutect2, varscan2
- CACNA1I | c.4064G>A p.R1355H | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV60808018; called by muse, mutect2, varscan2
- CASK | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100587395, COSV59366448; called by muse, mutect2, varscan2
- CFAP54 | c.5701C>T p.L1901F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV61572136; called by muse, mutect2, varscan2
- CLCN4 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66466483; called by muse, mutect2, varscan2
- COL18A1 | c.4387G>A p.E1463K (on ENST00000359759 / NM_130444.3; = p.E1228K on NM_030582.4) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201265799, COSV60588234; called by muse, mutect2, varscan2
- COL8A1 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53734435; called by muse, mutect2, varscan2
- CRACR2A | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV52912752; called by muse, mutect2, varscan2
- CTNNA3 | c.2456T>C p.V819A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65524444; called by muse, mutect2, varscan2
- CYP17A1 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs902026264, COSV64004920; called by muse, mutect2, varscan2
- DCDC1 | c.4762C>T p.R1588* (on ENST00000597505 / NM_001367979.1; = p.R695* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs768124594, COSV57999163; called by muse, mutect2, varscan2
- DDR2 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as rs1218815846, COSV100906237, COSV63370957; called by muse, mutect2, varscan2
- DNAJC16 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65448523; called by muse, mutect2, varscan2
- EIF4A1 | c.346-1G>T p.X116_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV51510752; called by muse, mutect2
- ERCC4 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs753728949, COSV61312009; called by muse, mutect2, varscan2
- FAM71A | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.084); catalogued as COSV54235640, COSV54235901; called by muse, mutect2, varscan2
- FBH1 | c.88C>T p.Q30* (on ENST00000362091 / NM_178150.3; = p.Q81* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV62982550; called by muse, mutect2, varscan2
- FHL1 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.49); catalogued as rs199818971, COSV61780957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSIP2 | c.17141T>C p.V5714A | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58085459; called by muse, mutect2, varscan2
- GABRG2 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV62717967; called by muse, mutect2, varscan2
- GIGYF1 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748394437, COSV51941749; called by muse, mutect2, varscan2
- GLIPR1 | c.709T>C p.F237L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV56990920; called by muse, mutect2, varscan2
- GPR149 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV67666950; called by muse, mutect2, varscan2
- GRID2 | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV56204584, COSV56211483; called by muse, mutect2, varscan2
- HS6ST2 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63712917; called by muse, mutect2, varscan2
- HS6ST2 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63712923; called by muse, mutect2, varscan2
- IFIT2 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.514); catalogued as COSV51078901; called by muse, mutect2, varscan2
- IGLV2-11 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as rs747047277; called by muse, mutect2, varscan2
- IL12RB2 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs371557250; called by muse, mutect2, varscan2
- IL20 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV65584548; called by muse, mutect2, varscan2
- INTS6 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60878061; called by muse, mutect2, varscan2
- IPO4 | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV55779501; called by muse, mutect2, varscan2
- IRAK3 | c.466C>G p.Q156E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as COSV54161718; called by muse, mutect2, varscan2
- ITGB4 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV52325770, COSV52332086; called by muse, mutect2, varscan2
- ITPKB | c.2652C>G p.I884M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55260261, COSV55261632; called by muse, mutect2, varscan2
- KCNN2 | c.247G>A p.G83R (on ENST00000264773; = p.G295R on NM_021614.4) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.671); catalogued as rs1351272122, COSV53288461; called by muse, mutect2, varscan2
- LEPR | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV60754459; called by muse, mutect2, varscan2
- LIMA1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs781115938, COSV57965417, COSV57966712; called by muse, mutect2, varscan2
- LIPK | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746906133, COSV68201040; called by muse, mutect2, varscan2
- LMAN1 | c.584G>C p.R195P | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826827, COSV99195313; called by muse, mutect2, varscan2
- LRRC36 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV99338586; called by muse, mutect2
- LRRTM4 | c.1362G>A p.M454I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV69140093; called by muse, mutect2, varscan2
- MMP12 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58259811; called by muse, mutect2, varscan2
- MRPS22 | c.132C>G p.F44L | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV60349872; called by muse, mutect2, varscan2
- MTRR | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs976647712, COSV52943779; called by muse, mutect2, varscan2
- MYBPH | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146696842; called by muse, mutect2, varscan2
- NOTCH1 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53050614, COSV53059882; called by muse, mutect2, varscan2
- NRAP | c.3229C>T p.L1077F (on ENST00000359988 / NM_001322945.2; = p.L1042F on NM_006175.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV63490523; called by muse, mutect2, varscan2
- NYAP1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs368554898, COSV55718797; called by muse, mutect2, varscan2
- OR2T6 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63216240; called by muse, mutect2, varscan2
- OR2T8 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100178562, COSV60662573; called by muse, mutect2, varscan2
- OR52J3 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV66746911; called by muse, mutect2
- PCDHGA1 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV65295957; called by muse, mutect2, varscan2
- PCDHGB3 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs1300952227, COSV53945968; called by muse, mutect2, varscan2
- PNLIPRP3 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV65047996; called by muse, mutect2, varscan2
- PRDM11 | c.529G>A p.G177S (on ENST00000530656 / NM_001359633.1; = p.G143S on NM_001256695.1) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778999417, COSV55439893; called by muse, mutect2, varscan2
- PRSS12 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56606223; called by muse, mutect2, varscan2
- PTPRB | c.4559C>A p.S1520Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54240337; called by muse, mutect2, varscan2
- RAP1GAP | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99265054; called by muse, mutect2
- RBMXL2 | c.1172G>C p.R391T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1465598408, COSV60980015; called by muse, mutect2, varscan2
- REXO1 | c.1876G>A p.V626I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs777825230, COSV50077854; called by muse, mutect2, varscan2
- RFX6 | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV60584903, COSV60586331; called by muse, mutect2, varscan2
- SEC24D | c.390C>A p.N130K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as COSV54879654; called by muse, mutect2, varscan2
- SKOR1 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.033); catalogued as rs982051327, COSV58245887; called by muse, mutect2, varscan2
- SLC44A1 | c.1423G>C p.A475P | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58264336; called by muse, mutect2, varscan2
- SLC9A6 | c.1511T>C p.L504S | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV65787967; called by muse, mutect2, varscan2
- SLFN13 | c.2681A>G p.Y894C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs778731610, COSV99539898; called by muse, mutect2, varscan2
- STK11IP | c.1527G>T p.E509D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.154); catalogued as COSV55249089; called by muse, mutect2
- STN1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.168); catalogued as rs183917764; called by muse, mutect2, varscan2
- STOML3 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 29/38 reads (76%) | catalogued as COSV65510695; called by muse, mutect2, varscan2
- STYXL2 | c.3320G>A p.R1107K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54805031; called by muse, mutect2, varscan2
- TASOR2 | c.3367T>G p.Y1123D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as COSV60167426; called by muse, mutect2, varscan2
- TNFRSF10C | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV63511639; called by muse, mutect2, varscan2
- TNRC6A | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.158); catalogued as COSV59364199; called by muse, mutect2, varscan2
- TNXB | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100926158; called by muse, mutect2
- TTYH3 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as COSV99349665, COSV99350158; called by muse, mutect2
- TUBG1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs777881464, COSV52221154; called by muse, mutect2, varscan2
- USP21 | c.1381C>T p.L461F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1477554614, COSV57088581; called by muse, mutect2, varscan2
- XPNPEP2 | c.1974G>C p.W658C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.174); catalogued as COSV64368906; called by muse, mutect2, varscan2
- ZC3H12A | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749195404, COSV66104115; called by muse, mutect2, varscan2
- ZNF462 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV52934298, COSV52937920; called by muse, mutect2, varscan2
- ZNF597 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV57084310; called by muse, mutect2, varscan2
- ZNF677 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV61720250; called by muse, mutect2, varscan2
- MTMR14 | c.1617_1627del p.V540Pfs*41 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- PTPRC | c.2340_2342del p.V781del | In Frame Del (DEL) | VAF 9/25 reads (36%) | called by pindel, varscan2
- RAB11FIP5 | c.647C>A p.A216D | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.052); called by muse, mutect2
- ACSM1 | c.684G>C p.G228= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV54635725; called by muse, mutect2, varscan2
- AGBL1 | c.276A>G p.G92= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV69799206; called by muse, mutect2, varscan2
- APOOL | c.678A>G p.E226= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV64271677; called by muse, mutect2, varscan2
- CLCN4 | c.678G>C p.P226= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV66466490; called by muse, mutect2, varscan2
- DNAH17 | c.6423C>T p.L2141= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1342146780, COSV67754173; called by muse, mutect2, varscan2
- DSEL | c.1218C>T p.L406= | Silent (SNP) | VAF 70/102 reads (69%) | catalogued as rs780461282, COSV59491437; called by muse, mutect2, varscan2
- FAM120B | c.552C>T p.I184= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as COSV53003740; called by muse, mutect2, varscan2
- FCGBP | c.10461G>A p.A3487= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs779999845; called by muse, mutect2, varscan2
- FTCD | c.1314G>A p.A438= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs777750537, COSV52425455; ClinVar: likely benign; called by muse, mutect2
- HK2 | c.1329C>T p.L443= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV51875380, COSV51880387; called by muse, mutect2, varscan2
- IL26 | c.282T>C p.F94= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV57488939; called by muse, mutect2, varscan2
- ITSN1 | c.4608C>T p.D1536= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs75569856, COSV101181628; called by muse, mutect2, varscan2
- KDM5C | c.96G>C p.A32= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV62891014, COSV62891200; called by muse, mutect2, varscan2
- KIAA1217 | c.3195G>A p.T1065= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1278335671, COSV56814803; called by muse, mutect2, varscan2
- KIFBP | c.1575A>G p.R525= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV62831711; called by muse, mutect2, varscan2
- KRT85 | c.240C>T p.F80= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs778706364, COSV57736391; called by muse, mutect2, varscan2
- LOXL4 | c.1680C>T p.H560= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs778061702, COSV53256573; called by muse, mutect2, varscan2
- LRRK1 | c.2208C>G p.L736= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs749633209, COSV52611197; called by muse, mutect2, varscan2
- MACF1 | c.10017C>T p.F3339= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV57111200, COSV57120713; called by muse, mutect2, varscan2
- PLXNA4 | c.4437C>T p.G1479= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs762377518, COSV58116557; called by muse, mutect2, varscan2
- PPP6R3 | c.2388C>T p.G796= (on ENST00000393800 / NM_001352375.2; = p.G716= on NM_018312.5) | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs563005506, COSV99676117; called by muse, mutect2, varscan2
- PRAME | c.105G>A p.L35= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV101287001; called by muse, mutect2, varscan2
- RXFP2 | c.1620C>T p.V540= | Silent (SNP) | VAF 57/84 reads (68%) | catalogued as COSV53635634; called by muse, mutect2, varscan2
- SPANXB1 | c.237A>C p.R79= | Silent (SNP) | VAF 53/1084 reads (5%) | called by muse, mutect2
- SV2A | c.2067G>A p.L689= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV64964745; called by muse, mutect2, varscan2
- THBS4 | c.132C>T p.G44= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs367779999; called by muse, mutect2, varscan2
- TRMT1 | c.108G>A p.A36= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV52834703; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824727 G>A | 5'Flank (SNP) | VAF 25/108 reads (23%) | catalogued as rs188756044; called by muse, mutect2, varscan2
- EFCAB13 | c.-1G>C | 5'UTR (SNP) | VAF 13/32 reads (41%) | catalogued as COSV58948345; called by muse, mutect2, varscan2
